Somatic mutation profile of tumor specimen BA2600D (aliquot aq-BA2600D) from BEATAML1.0 case 2254, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.7 years (23,641 days).
Specimen BA2600D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 297b70a1-72a6-4c30-acfb-9be67f3d33bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2884D (Solid Tissue Normal), aliquot aq-BA2884D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cb7bc73-8288-4e59-87de-4dc7843f1e17

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 35/72 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.667C>T p.R223C (on ENST00000372530 / NM_001198934.2; = p.R180C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs371964238; called by muse, mutect2, varscan2
- C19orf44 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.947); catalogued as rs767074023; called by muse, mutect2, varscan2
- CADPS2 | c.3268A>G p.K1090E | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); catalogued as rs1316733387; called by mutect2, varscan2
- CBARP | c.319G>A p.E107K (on ENST00000382477; = p.E113K on NM_152769.3) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs767203231, COSV53071463; called by muse, varscan2
- CNTNAP3B | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs1488677047; called by muse, mutect2, varscan2
- MFSD10 | c.245G>A p.R82K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.026); catalogued as rs769933508; called by muse, mutect2, varscan2
- SLC1A7 | c.676G>A p.V226I | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.792); catalogued as rs771978476; called by muse, mutect2
- TBX2 | c.92C>A p.A31E | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs768992923; called by muse, mutect2, varscan2
- ATAD5 | c.3347C>A p.S1116* | Nonsense Mutation (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2, varscan2
- CCDC58 | c.160A>C p.K54Q | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- CEP162 | c.321A>C p.E107D | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.7); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CLMN | c.2868G>T p.M956I | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2
- ERN2 | c.761A>G p.H254R | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC15 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.392); called by muse, varscan2
- NUP58 | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, varscan2
- RUNX1 | c.1207C>T p.P403S (on ENST00000344691 / NM_001001890.3; = p.P430S on NM_001754.5) | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SSC5D | c.3376G>T p.D1126Y | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ZNF354C | c.653G>T p.C218F | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- BARX1 | c.42G>T p.P14= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- CYP46A1 | c.564C>A p.A188= | Silent (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2
- KIAA1210 | c.4236C>T p.S1412= | Silent (SNP) | VAF 42/107 reads (39%) | called by muse, mutect2, varscan2
- PTPN21 | c.2109C>T p.D703= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV60851193; called by muse, mutect2, varscan2
- CDH15 | chr16:89168663 G>T | 5'Flank (SNP) | VAF 36/74 reads (49%) | catalogued as rs771808524; called by muse, varscan2
